Somatic mutation profile of tumor specimen MP2PRT-PAUGSG-TMP1-A (aliquot MP2PRT-PAUGSG-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUGSG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,080 days).
Specimen MP2PRT-PAUGSG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16f3775c-4ba2-4e6c-b01b-08cb45b01fca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUGSG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUGSG-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e758b70b-ee90-4e20-8607-2d05dcb45527

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Nonsense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.1998G>C p.K666N | Missense Mutation (SNP) | VAF 90/323 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377023736, COSV59205777, COSV59205799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 45/936 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1316200678; called by muse, mutect2
- DGKH | c.3238C>T p.R1080* | Nonsense Mutation (SNP) | VAF 125/322 reads (39%) | catalogued as rs368268622; called by muse, mutect2, varscan2
- EPHA6 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 36/335 reads (11%) | catalogued as COSV67571138, COSV67578619; called by muse, mutect2, varscan2
- ERCC8 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 12/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as CM163462; called by muse, mutect2
- OR7G1 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 15/469 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1454065381; called by muse, mutect2
- PCDH11X | c.1655G>A p.S552N | Missense Mutation (SNP) | VAF 18/552 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV53455873; called by muse, mutect2
- PCDHGB5 | c.240G>C p.E80D | Missense Mutation (SNP) | VAF 48/347 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs1480641333; called by muse, mutect2, varscan2
- PNMA6E | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 15/433 reads (3%) | SIFT deleterious (0.04); catalogued as rs991209116; called by muse, mutect2
- PRKCZ | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 38/376 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.137); catalogued as rs745674432, COSV101057565, COSV66067938; called by muse, mutect2
- TUBGCP6 | c.4733C>T p.S1578F | Missense Mutation (SNP) | VAF 28/771 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV50588847, COSV99954649; called by muse, mutect2
- CALML4 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 142/396 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- DDHD2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DNAI3 | c.1209C>G p.F403L | Missense Mutation (SNP) | VAF 18/269 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- FNBP1L | c.1594G>A p.E532K (on ENST00000271234 / NM_001164473.2; = p.E474K on NM_017737.5) | Missense Mutation (SNP) | VAF 95/324 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GNAI3 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 13/353 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.061); called by muse, mutect2
- MAGEB3 | c.600G>C p.K200N | Missense Mutation (SNP) | VAF 195/515 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC4 | c.4589C>T p.S1530F | Missense Mutation (SNP) | VAF 70/511 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- NLGN1 | c.1892C>G p.S631* | Nonsense Mutation (SNP) | VAF 14/472 reads (3%) | called by muse, mutect2
- OR4D9 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 131/435 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- PRPF38A | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 23/350 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2
- RNASE12 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 40/432 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.062); called by muse, mutect2
- RTN4 | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 52/980 reads (5%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.017); called by muse, mutect2
- ZNFX1 | c.2286G>A p.M762I | Missense Mutation (SNP) | VAF 15/336 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.053); called by muse, mutect2
- ZSCAN26 | c.508G>T p.E170* (on ENST00000623276 / NM_001111039.2; = p.E36* on NM_152736.5) | Nonsense Mutation (SNP) | VAF 70/273 reads (26%) | called by muse, mutect2, varscan2
- BFSP2 | c.93G>C p.R31= | Silent (SNP) | VAF 315/726 reads (43%) | called by muse, mutect2, varscan2
- CIRBP | c.39G>C p.L13= | Silent (SNP) | VAF 12/456 reads (3%) | called by muse, mutect2
- CPT1C | c.1398C>T p.L466= | Silent (SNP) | VAF 80/372 reads (22%) | catalogued as COSV54923272; called by muse, mutect2, varscan2
- EXOSC6 | c.561C>T p.L187= | Silent (SNP) | VAF 221/639 reads (35%) | called by muse, mutect2, varscan2
- NUP85 | c.1563C>T p.L521= | Silent (SNP) | VAF 12/366 reads (3%) | catalogued as COSV55457442; called by muse, mutect2
- RIMBP2 | c.429C>T p.S143= | Silent (SNP) | VAF 132/433 reads (30%) | catalogued as rs765478893, COSV55469143; called by muse, mutect2, varscan2
- SLC6A16 | c.471C>G p.L157= | Silent (SNP) | VAF 173/429 reads (40%) | called by muse, mutect2, varscan2
- TBC1D17 | c.504C>G p.L168= | Silent (SNP) | VAF 20/585 reads (3%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-51545G>A | Intron (SNP) | VAF 34/102 reads (33%) | catalogued as rs1044931562, COSV67440801; called by muse, varscan2
